Somatic mutation profile of tumor specimen MP2PRT-PAUNHM-TMP1-A (aliquot MP2PRT-PAUNHM-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUNHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,820 days).
Specimen MP2PRT-PAUNHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aaa2c32-a4a4-4369-8ed9-7250c9d9400f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNHM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNHM-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0744fe4a-e1c6-45e0-9210-15f6a7f59cc3

The open-access MAF lists 103 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 22, Nonsense Mutation 2, Intron 2, RNA 1, Translation Start Site 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.6977G>A p.R2326Q | Missense Mutation (SNP) | VAF 43/639 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.773); catalogued as rs746995743; called by muse, mutect2
- AKAP13 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 186/417 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV63461427; called by muse, mutect2, varscan2
- ANO7 | c.2708C>T p.T903M (on ENST00000274979; = p.T849M on NM_001370694.2) | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs765455537; called by muse, mutect2, varscan2
- BEND3 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 214/447 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV64681906; called by muse, mutect2, varscan2
- CFAP43 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 72/503 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779497114, COSV53377694; called by muse, mutect2, varscan2
- CFAP91 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1207533384, COSV56338737; called by muse, mutect2, varscan2
- CHST9 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775869190; called by muse, mutect2, varscan2
- CIDEA | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 232/462 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs149856588; called by muse, mutect2, varscan2
- DIAPH2 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 78/613 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100230484, COSV61260565; called by muse, mutect2, varscan2
- DNAH2 | c.12517G>A p.G4173R | Missense Mutation (SNP) | VAF 203/467 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs770953477; called by muse, mutect2, varscan2
- DUXB | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 72/442 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as rs545048613; called by muse, mutect2, varscan2
- GTF2H4 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 227/524 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV99461643; called by muse, mutect2, varscan2
- KCND3 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56189476; called by muse, mutect2
- KRBA1 | c.2059G>A p.G687S | Missense Mutation (SNP) | VAF 46/636 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as rs769219034; called by muse, mutect2
- KRT71 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 248/544 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs550629330, COSV99921886; called by muse, mutect2, varscan2
- MAGEC1 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 44/912 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as COSV99596491; called by muse, mutect2
- MAMDC2 | c.386G>C p.S129T | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65858657; called by muse, mutect2
- MCOLN3 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 68/422 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs369130424; called by muse, mutect2, varscan2
- NCOR1 | c.2909C>G p.S970* | Nonsense Mutation (SNP) | VAF 20/453 reads (4%) | catalogued as COSV99246453; called by muse, mutect2
- NEFM | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 80/580 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs765561281; called by muse, varscan2
- PLG | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57514734, COSV57521006; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1566G>A p.M522I (on ENST00000421990 / NM_001136042.2; = p.M504I on NM_025267.3) | Missense Mutation (SNP) | VAF 18/591 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1386771234; called by muse, mutect2
- PTS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/566 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as CM121708; called by muse, mutect2
- RAPGEF2 | c.1050G>C p.M350I | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52424371; called by muse, mutect2, varscan2
- SLC25A20 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs553582613; called by muse, mutect2, varscan2
- SOX5 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 48/666 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs773273637, COSV58631543; called by muse, mutect2
- SULT4A1 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs374057069, COSV50782525; called by muse, mutect2, varscan2
- TDRD9 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 119/264 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs757354863, COSV100175638; called by muse, mutect2, varscan2
- USP9X | c.2545C>T p.R849* | Nonsense Mutation (SNP) | VAF 74/484 reads (15%) | catalogued as COSV61074374; called by muse, mutect2, varscan2
- VEPH1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100747861; called by muse, mutect2
- WDFY4 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 86/569 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs1345078998, COSV57434510; called by muse, mutect2, varscan2
- ZNF564 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 231/514 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as rs1381944612, COSV59435803; called by muse, mutect2, varscan2
- ZNF723 | c.996G>C p.K332N | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV74103297; called by muse, mutect2
- AP1G2 | c.1410+1G>A p.X470_splice | Splice Site (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- ARHGEF7 | c.74C>G p.S25W | Missense Mutation (SNP) | VAF 48/716 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- BLM | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.097); called by muse, mutect2
- C1orf21 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH1 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 19/656 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CDH11 | c.2163C>G p.I721M | Missense Mutation (SNP) | VAF 81/564 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CDK5RAP2 | c.4069C>A p.H1357N | Missense Mutation (SNP) | VAF 41/537 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- CLIP1 | c.2959G>C p.E987Q (on ENST00000620786 / NM_001247997.1; = p.E976Q on NM_002956.2) | Missense Mutation (SNP) | VAF 16/584 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); called by muse, mutect2
- COPG2 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2
- CUBN | c.3275A>T p.N1092I | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CYLC1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.094); called by muse, mutect2
- DEPDC1 | c.1547G>A p.R516K | Missense Mutation (SNP) | VAF 205/448 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DNAH2 | c.9555C>G p.I3185M | Missense Mutation (SNP) | VAF 38/654 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2
- EPB41L3 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 39/645 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM71C | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 226/489 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR151 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- GPR153 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 66/806 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- IL20RA | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 43/573 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- KLF9 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 169/355 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MATN2 | c.1568G>C p.C523S | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MRS2 | c.306G>C p.R102S | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2
- MTERF1 | c.214A>T p.N72Y | Missense Mutation (SNP) | VAF 18/431 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- MTREX | c.1997G>C p.G666A | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- NUP155 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- OAZ1 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 51/373 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RXFP2 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 66/476 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SEC16B | c.750T>A p.D250E | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORBS2 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 36/659 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- STN1 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 156/377 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- SVIL | c.6077C>G p.S2026C (on ENST00000355867 / NM_021738.3; = p.S1600C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2
- TBC1D10A | c.618G>C p.L206F | Missense Mutation (SNP) | VAF 233/516 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TLL1 | c.2422C>G p.P808A | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2
- TPP2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- TRIP12 | c.4111G>C p.E1371Q | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSC22D1 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- UNC5B | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNKL | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 28/771 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- USP34 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 60/588 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); called by muse, mutect2
- UTP14A | c.1448C>A p.T483N | Missense Mutation (SNP) | VAF 22/798 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- WDFY4 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 50/483 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZC3H7A | c.2380C>G p.H794D | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF679 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZP3 | c.1072G>T p.A358S (on ENST00000394857 / NM_001110354.2; = p.A307S on NM_007155.6) | Missense Mutation (SNP) | VAF 181/481 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AKAP4 | c.2130C>T p.I710= | Silent (SNP) | VAF 79/606 reads (13%) | called by muse, mutect2, varscan2
- ANKRD30B | c.198G>C p.L66= | Silent (SNP) | VAF 12/376 reads (3%) | called by muse, mutect2
- B3GAT1 | c.699C>T p.N233= | Silent (SNP) | VAF 93/607 reads (15%) | catalogued as rs762279455; called by muse, mutect2, varscan2
- BAHCC1 | c.6663G>A p.E2221= | Silent (SNP) | VAF 30/828 reads (4%) | called by muse, mutect2
- CCDC180 | c.1752C>T p.L584= | Silent (SNP) | VAF 135/303 reads (45%) | called by muse, mutect2, varscan2
- CSAD | c.1323C>G p.L441= (on ENST00000444623 / NM_001244705.2; = p.L468= on NM_015989.5) | Silent (SNP) | VAF 27/422 reads (6%) | called by muse, mutect2
- CTNNAL1 | c.72C>T p.F24= | Silent (SNP) | VAF 111/686 reads (16%) | catalogued as rs1166231163, COSV57705086; called by muse, mutect2, varscan2
- DNAAF2 | c.408C>T p.S136= | Silent (SNP) | VAF 141/946 reads (15%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.2082G>A p.A694= (on ENST00000265755 / NM_016328.3; = p.A679= on NM_005685.4) | Silent (SNP) | VAF 54/623 reads (9%) | catalogued as rs193094382, COSV56088939; called by muse, mutect2
- IL1RAP | c.888C>G p.V296= | Silent (SNP) | VAF 87/226 reads (38%) | called by muse, mutect2, varscan2
- KIAA1671 | c.1467G>A p.E489= | Silent (SNP) | VAF 52/490 reads (11%) | called by muse, mutect2
- NCOR1 | c.3372C>T p.V1124= | Silent (SNP) | VAF 15/444 reads (3%) | called by muse, mutect2
- PHF21B | c.594C>T p.H198= | Silent (SNP) | VAF 30/317 reads (9%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3246C>A p.G1082= | Silent (SNP) | VAF 99/252 reads (39%) | called by muse, mutect2, varscan2
- PLEKHS1 | c.426C>G p.L142= (on ENST00000369310 / NM_182601.1; = p.L148= on NM_024889.5) | Silent (SNP) | VAF 107/239 reads (45%) | called by muse, mutect2, varscan2
- PLPP3 | c.849G>A p.T283= | Silent (SNP) | VAF 30/406 reads (7%) | catalogued as rs773818825; called by muse, mutect2
- PLXNA4 | c.48C>G p.L16= | Silent (SNP) | VAF 21/412 reads (5%) | catalogued as COSV100326649; called by muse, mutect2
- SASH1 | c.237G>A p.E79= | Silent (SNP) | VAF 27/385 reads (7%) | catalogued as rs1485147414, COSV99054961; called by muse, mutect2
- SORCS1 | c.3321C>T p.L1107= | Silent (SNP) | VAF 63/447 reads (14%) | catalogued as rs1463178379; called by muse, mutect2, varscan2
- SPAG17 | c.834A>G p.L278= | Silent (SNP) | VAF 25/195 reads (13%) | called by muse, mutect2, varscan2
- TFDP3 | c.801C>T p.I267= | Silent (SNP) | VAF 68/928 reads (7%) | catalogued as COSV59538572; called by muse, mutect2
- TRAPPC10 | c.81G>A p.Q27= | Silent (SNP) | VAF 30/494 reads (6%) | called by muse, mutect2
- AL353804.4 | chrX:73823210 C>T | 5'Flank (SNP) | VAF 43/344 reads (13%) | called by muse, mutect2, varscan2
- ANO8 | c.-48C>T | 5'UTR (SNP) | VAF 44/972 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+475C>T | Intron (SNP) | VAF 40/634 reads (6%) | called by muse, mutect2
- DCHS2 | n.2082G>T | RNA (SNP) | VAF 26/546 reads (5%) | called by muse, mutect2
- TCEAL4 | c.-22-404G>C | Intron (SNP) | VAF 48/644 reads (7%) | called by muse, mutect2
